MMRF case MMRF_1888 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/fdc2ef83-7244-4db6-a417-989c9625b927

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 64.8 years (23,685 days); ISS stage: II; Days to last known disease status: 1,046 days (2.9 years); Days to last follow up: 1,046 days (2.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 29 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 85 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 143 days; Days to treatment end: 143 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 388 days (1.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -58 (ECOG 0): M Protein 4.06 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.7 mg/dL; Immunoglobulin G 51.5 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 9.8 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 267 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.3 mmol/L; Albumin 33 g/L; Total Protein 10.1 g/dL; Glucose 4.46 mmol/L.
- Day 68 (ECOG 0): M Protein 0.925 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.33 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.967 mg/dL; Immunoglobulin G 13.2 g/L; Immunoglobulin A 0.36 g/L; Immunoglobulin M 0.37 g/L; Hemoglobin 7.19 mmol/L; Leukocytes 14.3 ×10⁹/L; Absolute Neutrophil 11.2 ×10⁹/L; Platelets 289 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.8 g/dL; Glucose 6.55 mmol/L.
- Day 166 (ECOG 1): M Protein 0.0462 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.285 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.827 mg/dL; Immunoglobulin G 6.27 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.67 g/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 46 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.6 g/dL; Glucose 6.71 mmol/L.
- Day 227 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.676 mg/dL; Immunoglobulin G 5.74 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.32 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 4.35 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.4 mmol/L; Albumin 42 g/L; Total Protein 6.8 g/dL; Glucose 6.22 mmol/L.
- Day 276 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.451 mg/dL; Immunoglobulin G 5.35 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.36 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 5.17 mmol/L.
- Day 332 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.284 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 5.23 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.29 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 197 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 5.01 mmol/L.
- Day 493 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.746 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.12 mg/dL; Immunoglobulin G 7.42 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.31 g/L; Hemoglobin 7.56 mmol/L; Leukocytes 78.4 ×10⁹/L; Absolute Neutrophil 57.5 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 6.27 mmol/L.
- Day 675 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.856 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.69 mg/dL; Immunoglobulin G 8.01 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 229 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6 mmol/L.
- Day 864 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.28 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.18 mg/dL; Immunoglobulin G 5.89 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.27 g/L; Hemoglobin 7.94 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 6.1 g/dL; Glucose 5.45 mmol/L.
- Day 1,046 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.25 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.88 mg/dL; Immunoglobulin G 6.84 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.28 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.77 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 38 g/L; Total Protein 6.6 g/dL; Glucose 7.65 mmol/L.

Other clinical attributes
- Day -58: Weight: 73 kg; Height: 152 cm.

Family history
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1888_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -58 days.
- Sample MMRF_1888_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -58 days.
